Somatic mutation profile of tumor specimen TCGA-C5-A905-01A (aliquot TCGA-C5-A905-01A-11D-A37N-09) from TCGA case TCGA-C5-A905, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 37.2 years (13,584 days).
Specimen TCGA-C5-A905-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c673b94d-8441-4f5a-9a5d-ea73da3c33c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A905-10A (Blood Derived Normal), aliquot TCGA-C5-A905-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a2d0852-eaf9-455c-8406-12ae0dceef12

The open-access MAF lists 86 somatic variants for this specimen: 65 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 19, Nonsense Mutation 4, RNA 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.1726G>A p.E576K (on ENST00000373394 / NM_001271696.3; = p.E577K on NM_004299.6) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV53719637; called by muse, mutect2, varscan2
- ADH4 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1463323615, COSV99644225; called by muse, mutect2, varscan2
- ADRM1 | c.978G>C p.E326D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV99440427; called by muse, mutect2
- AGBL1 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs774676310, COSV66862130; called by muse, mutect2, varscan2
- AGBL2 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100101752; called by muse, mutect2
- AMPD1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1214311723, COSV62416846; called by muse, mutect2, varscan2
- BTK | c.1573C>G p.R525G | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as CM950171, CM980277; called by muse, mutect2
- C6 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs777970989, COSV54707306, COSV99667195; called by muse, mutect2, varscan2
- CD6 | c.1138_1141del p.T380Sfs*3 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs749358989; called by mutect2, pindel, varscan2
- CDK12 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV101420476; called by muse, mutect2, varscan2
- CDKN2A | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.769); catalogued as COSV100446641; called by muse, mutect2, varscan2
- CDKN2A | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.769); catalogued as COSV100446643, COSV58714967; called by muse, mutect2, varscan2
- COL26A1 | c.1010G>A p.R337Q (on ENST00000313669 / NM_001278563.3; = p.R335Q on NM_133457.4) | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs868326218, COSV100561811; called by muse, mutect2, varscan2
- DOCK8 | c.3127G>C p.E1043Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV101209950; called by muse, mutect2, varscan2
- DTL | c.1643G>A p.R548K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV100877227; called by muse, mutect2, varscan2
- EIF5B | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99177304; called by muse, mutect2, varscan2
- EPHB1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770070877, COSV101213247, COSV67675179; called by muse, mutect2, varscan2
- FBXO44 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV99278815, COSV99278977; called by muse, mutect2, varscan2
- GATAD2B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100897894, COSV100898018; called by muse, mutect2, varscan2
- HOOK1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs370424578; called by muse, mutect2, varscan2
- HSPG2 | c.10057G>C p.E3353Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV101013481; called by muse, mutect2, varscan2
- INPP5E | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as rs1428164960, COSV99258754; called by muse, mutect2
- IRAG2 | c.3839G>A p.R1280K (on ENST00000636465; = p.R325K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100209412; called by muse, mutect2
- ITGA4 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99276433; called by muse, mutect2, varscan2
- ITGAL | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs145951975; called by muse, mutect2, varscan2
- LINGO2 | c.1429G>C p.D477H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430639; called by muse, mutect2, varscan2
- MAP7D3 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100286400; called by muse, mutect2
- MCTP1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100387411; called by muse, mutect2, varscan2
- NCK1 | c.649A>G p.M217V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99999602; called by muse, mutect2, varscan2
- NNT | c.3253C>T p.Q1085* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52926704, COSV99239037; called by muse, mutect2, varscan2
- PCBP1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100340167; called by muse, mutect2, varscan2
- PCDHGB6 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as COSV53984266, COSV54055529; called by muse, mutect2, varscan2
- PCIF1 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100533103, COSV59816215; called by muse, mutect2
- PHF8 | c.1140C>G p.L380= (on ENST00000357988 / NM_001184896.1; = p.L344= on NM_015107.3) | Splice Region (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100154325; called by muse, mutect2, varscan2
- PHLPP1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372737422; called by muse, mutect2, varscan2
- PPEF1 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.109); catalogued as COSV100583804, COSV100584097; called by muse, mutect2, varscan2
- PPP2R3C | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV54831658, COSV99805809; called by muse, mutect2, varscan2
- RBM47 | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs149580961; called by muse, mutect2, varscan2
- SCUBE3 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs757219770, COSV99234584; called by muse, mutect2, varscan2
- SLC26A5 | c.2058C>A p.D686E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100100419; called by muse, mutect2
- SPATS2L | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100660754; called by muse, mutect2, varscan2
- SPHK2 | c.1327A>T p.I443F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99709428; called by muse, mutect2, varscan2
- STRBP | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV62116742; called by muse, mutect2, varscan2
- SVEP1 | c.6241C>G p.H2081D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99929206; called by muse, mutect2, varscan2
- SYNE1 | c.2176G>C p.E726Q (on ENST00000367255 / NM_182961.4; = p.E733Q on NM_033071.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.153); catalogued as COSV99567132; called by muse, mutect2, varscan2
- TBC1D16 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV100188115; called by muse, mutect2, varscan2
- TCHHL1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV100916547; called by muse, mutect2, varscan2
- TDRD5 | c.1953G>C p.L651F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54241216; called by muse, mutect2, varscan2
- THBS1 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1251274326, COSV52956983; called by muse, mutect2, varscan2
- TMEM126A | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs765038408, COSV99476315; called by muse, mutect2, varscan2
- TOR1AIP2 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100857438; called by muse, mutect2, varscan2
- TP63 | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53199618, COSV53214070; called by muse, mutect2, varscan2
- TRO | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs371236896, COSV51508000; called by muse, mutect2, varscan2
- U2SURP | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as COSV101204314, COSV101204495; called by muse, mutect2, varscan2
- USP5 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as rs1360610439; called by muse, mutect2
- VEGFC | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566826535, COSV54604159; called by muse, mutect2, varscan2
- VWCE | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1309095818, COSV100075914; called by muse, mutect2, varscan2
- WNT7B | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as rs756644553, COSV100255017; called by muse, mutect2, varscan2
- ZFHX4 | c.5987C>G p.S1996C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV50749513, COSV99263598; called by muse, mutect2, varscan2
- ZNF280B | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs144448744, COSV64529708; called by muse, mutect2, varscan2
- SPATA5L1 | c.2210dup p.L737Ffs*3 | Frame Shift Ins (INS) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- TTN | c.94696_94698del p.Y31566del (on ENST00000591111; = p.Y24142del on NM_003319.4) | In Frame Del (DEL) | VAF 15/43 reads (35%) | called by pindel, varscan2
- WASHC2A | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ADGRF4 | c.1170C>G p.L390= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV99348492; called by muse, mutect2, varscan2
- ATP4A | c.1711C>T p.L571= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99382661; called by muse, mutect2, varscan2
- ATP8B3 | c.3525G>A p.P1175= | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as rs777486565, COSV100034479; called by muse, mutect2, varscan2
- EZHIP | c.282G>A p.T94= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100539758; called by muse, mutect2, varscan2
- GHDC | c.1014C>T p.L338= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100054753; called by muse, mutect2, varscan2
- GLB1 | c.1011G>A p.L337= | Silent (SNP) | VAF 48/54 reads (89%) | catalogued as rs985237780, COSV100257401; called by muse, varscan2
- GRXCR1 | c.816G>A p.L272= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- INTS4 | c.1839C>T p.F613= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV71089661; called by muse, mutect2, varscan2
- PALB2 | c.1794G>C p.L598= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs182494675, COSV99848601; called by muse, mutect2, varscan2
- PCDH19 | c.3045C>T p.F1015= (on ENST00000373034 / NM_001184880.2; = p.F967= on NM_020766.3) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs746702101, COSV55261491; called by muse, mutect2, varscan2
- RELN | c.1656C>T p.V552= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- RNF166 | c.450C>T p.F150= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as rs138161076; called by mutect2, varscan2
- SAMD8 | c.126C>T p.I42= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV101014021; called by muse, mutect2, varscan2
- SDK1 | c.1212G>T p.V404= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV101269466; called by muse, mutect2, varscan2
- SGK2 | c.519C>T p.L173= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs761358833, COSV58314018; called by muse, mutect2, varscan2
- SLK | c.3096C>T p.F1032= | Silent (SNP) | VAF 52/89 reads (58%) | catalogued as COSV100211809; called by muse, mutect2, varscan2
- TBC1D10A | c.234G>T p.V78= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs780999777, COSV99304690; called by muse, mutect2, varscan2
- TTLL10 | c.687C>T p.L229= (on ENST00000379289 / NM_001130045.2; = p.L156= on NM_153254.3) | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV101016741; called by muse, mutect2, varscan2
- TTYH2 | c.234G>A p.A78= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs146849596; called by muse, mutect2, varscan2
- BIRC8 | n.1411G>A | RNA (SNP) | VAF 16/33 reads (48%) | catalogued as rs761492573, COSV70346634; called by muse, mutect2, varscan2
- FAM169B | n.641G>T | RNA (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100259873; called by muse, mutect2, varscan2
